Gene-level copy-number profile of tumor specimen TCGA-24-2271-01A from TCGA case TCGA-24-2271, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.8 years (20,399 days).
Specimen TCGA-24-2271-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.256a9e3d-46f8-465f-8157-354e3b9e47b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2271-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/121900e3-1b85-436f-9ebe-0be2621acd8a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 15,234; copy number 2: 39,289; copy number 3: 4,074; copy number 4: 1,189; copy number 5: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2271-01A-01D-0704-01): tumor purity 0.68, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,159,149, 1 gene (within-gene range 0–1): LINC00290.
- chr12:38,078,529–38,207,192, 9 genes: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:140,940,562–141,662,209, 22 genes, copy number 5: RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1.

Autosomal genes at a single copy (total copy number 1): 15,234. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
